Gene-level copy-number profile of tumor specimen TCGA-EO-A3AS-01A from TCGA case TCGA-EO-A3AS, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Endometrium; FIGO stage: Stage IA; Tumor grade: G3; Age at diagnosis: 86.1 years (31,450 days).
Specimen TCGA-EO-A3AS-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-UCEC.5616b45b-3b67-4ce3-a990-a4ca972bf7a1.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-EO-A3AS-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 806 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/632ebbf8-4229-424d-8920-577c3c019b52

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 40; copy number 1: 16,957; copy number 2: 30,125; copy number 3: 11,108; copy number 4: 1,060; copy number 5: 190; copy number 6: 6; copy number 7: 78; copy number 8: 253.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-EO-A3AS-01A-11D-A19X-01): tumor purity 0.79, ploidy 2.04, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 40 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:48,926,021–49,187,585, 2 genes (within-gene range 0–3): AL645507.1, AC099788.1.
- chr13:75,283,503–77,645,263, 35 genes (within-gene range 0–1): TBC1D4, AL139230.1, COMMD6, UCHL3, AL137782.1, LMO7-AS1, LMO7, AL137244.1, FAM204CP, LMO7DN, LMO7DN-IT1, LINC00561, LINC01034, RN7SL571P, AL136441.1, AL161717.1, AL365394.1, KCTD12, AC000403.1, BTF3P11, ACOD1, RPL7P44, DHX9P1, CLN5, AC001226.2, FBXL3, MYCBP2-AS1, AC001226.1, MYCBP2, MYCBP2-AS2, AL159158.1, SCEL, AL137140.1, SCEL-AS1, RNY3P7.
- chr16:89,420,075–89,453,678, 3 genes: AC092120.1, AC092120.3, RNU6-430P.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 527 genes in 8 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:164,769,116–164,774,641, 1 gene, copy number 6: PBX1-AS1.
- chr3:24,494,087–25,174,305, 7 genes, copy number 5–6 (within-gene range 3–6): THRB-AS1, AC012087.2, AC012087.1, EIF3KP2, AC092422.1, RN7SL216P, RNA5SP125.
- chr3:195,214,787–197,573,323, 93 genes, copy number 5 (broad region; genes not listed).
- chr3:197,580,344–197,580,629, 1 gene, copy number 5: AC132008.1.
- chr4:95,840,093–97,135,059, 9 genes, copy number 5: PDHA2, RNU6-1059P, RNU6-34P, AC096661.1, LINC02267, RN7SKP28, AC096585.1, COX7A2P2, AC108515.1.
- chr4:97,334,635–97,633,823, 2 genes, copy number 5 (within-gene range 4–5): AC034154.1, STPG2-AS1.
- chr8:65,526,738–69,110,574, 59 genes, copy number 5: LINC01299, AC100814.1, Y_RNA, ARMC1, MTFR1, AC055822.1, PDE7A, AC100812.1, DNAJC5B, AC084082.1, TRIM55, CRH, LINC00967, AC009879.4, RRS1-AS1, RRS1, AC009879.2, AC009879.3, ADHFE1, AC009879.1, VXN, RNU6-1324P, MYBL1, VCPIP1, Y_RNA, C8orf44-SGK3, C8orf44, SGK3, PTTG3P, MCMDC2, SNHG6, SNORD87, TCF24, PPP1R42, AC110998.1, COPS5, CSPP1, RNA5SP268, AC087359.1, ARFGEF1, AC021321.2, AC021321.1, AC011037.1, CPA6, NACAP10, AC022874.1, NDUFS5P6, PREX2, AC011853.2, AC011853.1, Y_RNA, RPL31P40, C8orf34-AS1, C8orf34, RPS15AP25, RNA5SP269, AC083967.1, LINC01592, RNU7-102P.
- chr8:110,105,076–141,367,286, 355 genes, copy number 5–8 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 15,458. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
